Somatic mutation profile of tumor specimen C3L-00961-01 (aliquot CPT0027320009) from CPTAC case C3L-00961, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 59.6 years (21,764 days).
Specimen C3L-00961-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecde175c-448f-4503-a9cf-41da2a6b4625.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00961-71 (Blood Derived Normal), aliquot CPT0027380002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c9ed2d7-5ec5-4971-a8b8-551990d3a822

The open-access MAF lists 64 somatic variants for this specimen: 37 protein-altering or splice-affecting, 19 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 19, Frame Shift Del 3, Intron 3, Nonsense Mutation 2, 3'UTR 2, RNA 2, Splice Region 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 16/264 reads (6%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 14/154 reads (9%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2
- PIK3CA | c.3061T>C p.Y1021H | Missense Mutation (SNP) | VAF 29/252 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV55901519, COSV55910253; called by muse, mutect2, varscan2
- PTEN | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 128/499 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121909218, CM115947, CM971272, COSV64289566, COSV64291659; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGPS | c.1780G>A p.V594I | Missense Mutation (SNP) | VAF 44/345 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.206); catalogued as rs764836897, COSV51561213; called by muse, mutect2, varscan2
- CA3 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 37/277 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs557237110, COSV53409536, COSV53411192; called by muse, mutect2, varscan2
- FAM200A | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs748186224; called by muse, mutect2
- FLNC | c.4295C>T p.P1432L | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1427806742; called by muse, mutect2, varscan2
- FTCD | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs757496597, COSV52426415; called by muse, mutect2, varscan2
- GRIA4 | c.1367A>G p.K456R | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as COSV56926479; called by muse, mutect2
- KRR1 | c.909+6G>A | Splice Region (SNP) | VAF 15/147 reads (10%) | catalogued as rs1490082255; called by muse, mutect2
- MCOLN1 | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747683527, COSV51173977; called by muse, mutect2, varscan2
- NKAPD1 | c.820C>T p.R274C (on ENST00000280352 / NM_001082970.2; = p.R275C on NM_018195.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.982); catalogued as rs368315610; called by muse, mutect2
- NLRP5 | c.1969G>A p.V657I | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.234); catalogued as rs370513314; called by muse, mutect2
- OBSCN | c.14746C>T p.R4916W | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs199529556, COSV52742151; called by muse, mutect2
- PTCHD3 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); catalogued as rs762103687, COSV71256468; called by muse, mutect2, varscan2
- RHPN1 | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs776053563, COSV100000330; called by muse, mutect2, varscan2
- SALL1 | c.1361G>A p.C454Y | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99192062; called by muse, mutect2, varscan2
- SLC26A9 | c.1966G>A p.V656I | Missense Mutation (SNP) | VAF 29/288 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs138933890; called by muse, mutect2, varscan2
- SMC1B | c.2849T>C p.I950T | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as rs780426114; called by muse, varscan2
- SPDYC | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs376375962; called by mutect2, varscan2
- STK11IP | c.941C>T p.T314I | Missense Mutation (SNP) | VAF 45/423 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.035); catalogued as rs1352671659; called by muse, mutect2
- TIMM17B | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs782375343; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1888G>A p.V630M | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs748233722, COSV54648471; called by muse, mutect2
- ZIC4 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs1036494828, COSV67170773, COSV67174229; called by muse, mutect2
- ARMC8 | c.1154T>A p.M385K (on ENST00000469044 / NM_001363941.2; = p.M371K on NM_015396.6) | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2
- ELFN1 | c.2194C>A p.R732S | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2
- FBXO4 | c.65_78del p.R22Hfs*28 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- FRMPD3 | c.5161G>C p.E1721Q | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- GPT2 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KANK3 | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF21B | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NAA15 | c.2301del p.A768Lfs*8 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel
- NCKAP5L | c.2707C>T p.R903* | Nonsense Mutation (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- REV1 | c.3128del p.G1043Afs*22 | Frame Shift Del (DEL) | VAF 30/258 reads (12%) | called by mutect2, pindel, varscan2
- TSPOAP1 | c.2094dup p.E699* | Frame Shift Ins (INS) | VAF 19/156 reads (12%) | called by mutect2, pindel, varscan2
- ZKSCAN2 | c.2735A>G p.E912G | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ASAP1 | c.1828C>A p.R610= | Silent (SNP) | VAF 15/155 reads (10%) | catalogued as rs201240224; called by muse, mutect2, varscan2
- BCORL1 | c.2397C>A p.T799= | Silent (SNP) | VAF 17/211 reads (8%) | called by muse, mutect2
- CASP8AP2 | c.1194A>G p.T398= | Silent (SNP) | VAF 12/127 reads (9%) | called by muse, mutect2, varscan2
- CCKBR | c.72G>A p.P24= | Silent (SNP) | VAF 16/151 reads (11%) | catalogued as COSV58101276; called by muse, mutect2, varscan2
- CDC25A | c.96C>A p.G32= | Silent (SNP) | VAF 25/175 reads (14%) | called by muse, mutect2, varscan2
- DMRTA1 | c.1278C>T p.Y426= | Silent (SNP) | VAF 26/240 reads (11%) | catalogued as rs369593156; called by muse, mutect2, varscan2
- DMXL1 | c.1875C>T p.L625= | Silent (SNP) | VAF 22/280 reads (8%) | catalogued as COSV60712399; called by muse, mutect2
- FUBP1 | c.486G>A p.R162= | Silent (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- IFIT3 | c.999C>T p.S333= | Silent (SNP) | VAF 18/193 reads (9%) | catalogued as rs758370886, COSV51078420, COSV51078833; called by muse, mutect2
- JADE1 | c.2319C>T p.H773= | Silent (SNP) | VAF 9/124 reads (7%) | called by muse, mutect2
- LYSMD1 | c.231C>T p.F77= | Silent (SNP) | VAF 18/256 reads (7%) | called by muse, mutect2
- MAP1B | c.1531C>T p.L511= | Silent (SNP) | VAF 26/278 reads (9%) | called by muse, mutect2
- N4BP3 | c.720C>T p.C240= | Silent (SNP) | VAF 12/220 reads (5%) | called by muse, mutect2
- NCL | c.1758G>A p.E586= | Silent (SNP) | VAF 20/238 reads (8%) | called by muse, mutect2
- PCDHB8 | c.1269C>T p.T423= | Silent (SNP) | VAF 46/1009 reads (5%) | catalogued as rs1554281148, COSV50760978; called by muse, mutect2
- PLA2G12A | c.354C>T p.G118= | Silent (SNP) | VAF 26/226 reads (12%) | called by muse, mutect2, varscan2
- PPP1R13B | c.2454G>A p.E818= | Silent (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- SCN2A | c.4884C>A p.I1628= | Silent (SNP) | VAF 32/489 reads (7%) | called by muse, mutect2
- ZNF689 | c.303G>A p.G101= | Silent (SNP) | VAF 10/115 reads (9%) | catalogued as COSV54909788; called by muse, mutect2
- ATP11A | c.*38C>T | 3'UTR (SNP) | VAF 47/418 reads (11%) | catalogued as rs747624023, COSV52123149, COSV52123360; called by muse, mutect2, varscan2
- FAM234A | c.577+407C>T | Intron (SNP) | VAF 12/92 reads (13%) | catalogued as rs773004400; called by muse, varscan2
- FRMD8P1 | n.321C>T | RNA (SNP) | VAF 32/260 reads (12%) | called by muse, mutect2, varscan2
- FUNDC2 | c.-6G>A | 5'UTR (SNP) | VAF 23/216 reads (11%) | catalogued as COSV64271205; called by muse, mutect2, varscan2
- LINC01630 | n.219+73207G>A | Intron (SNP) | VAF 39/330 reads (12%) | catalogued as rs1415414094; called by muse, mutect2, varscan2
- SNORD116-29 | n.23dup | RNA (INS) | VAF 15/110 reads (14%) | catalogued as rs749710113; called by mutect2, varscan2
- YME1L1 | c.339+31G>A | Intron (SNP) | VAF 25/268 reads (9%) | catalogued as rs1226482452; called by muse, mutect2
- ZC3H18 | c.*402C>G | 3'UTR (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
